Somatic mutation profile of tumor specimen TCGA-FS-A1ZA-06A (aliquot TCGA-FS-A1ZA-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.4 years (17,326 days).
Specimen TCGA-FS-A1ZA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01f60450-bdf1-4578-87fa-e973b9beea60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZA-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZA-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a21c005-793b-4d29-ad7b-c5c7a6e3dec4

The open-access MAF lists 1,446 somatic variants for this specimen: 959 protein-altering or splice-affecting, 454 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 872, Silent 454, Nonsense Mutation 55, Intron 17, Splice Region 12, Splice Site 11, RNA 8, Frame Shift Del 5, 5'Flank 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 2.

Variants (750 of 1,446; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138958917, CM014534, CM071620; ClinVar: pathogenic; called by muse, varscan2
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 46/92 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- NF1 | c.2352G>A p.W784* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs199474778, CM013773, CM076348, CM143339, COSV62213089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1634G>A p.G545E (on ENST00000373993 / NM_138932.2; = p.G537E on NM_014576.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs1328340424, COSV50971607; called by muse, mutect2
- A1CF | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50971746; called by muse, mutect2, varscan2
- ABCA12 | c.6629C>T p.S2210F (on ENST00000272895 / NM_173076.3; = p.S1892F on NM_015657.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55961716; called by muse, varscan2
- ABCA4 | c.3814-1G>A p.X1272_splice | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as COSV64674114; called by muse, mutect2, varscan2
- ABCB11 | c.3044G>A p.S1015N | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV55592810; called by muse, mutect2, varscan2
- ABCC10 | c.2600C>T p.A867V (on ENST00000372530 / NM_001198934.2; = p.A839V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); catalogued as rs1243647163, COSV55088771; called by muse, mutect2, varscan2
- ABCC4 | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65310671; called by muse, mutect2, varscan2
- ABCC4 | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100972599; called by muse, mutect2, varscan2
- AC093525.2 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | PolyPhen benign (0.005); catalogued as COSV53550989, COSV99565578; called by muse, mutect2, varscan2
- ACAD11 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.952); catalogued as COSV53896981, COSV99391986; called by muse, mutect2, varscan2
- ACER1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.076); catalogued as COSV56835691; called by muse, mutect2, varscan2
- ACSL4 | c.1945A>T p.I649L (on ENST00000340800 / NM_022977.2; = p.I608L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV61614660; called by muse, mutect2, varscan2
- ACSM1 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54636405; called by muse, varscan2
- ACSM4 | c.1206G>A p.Q402= | Splice Region (SNP) | VAF 3/12 reads (25%) | catalogued as COSV68067972; called by muse, mutect2
- ADAM28 | c.103A>G p.R35G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56101343; called by muse, mutect2, varscan2
- ADAMTS10 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs953799124, COSV54355537; called by muse, mutect2, varscan2
- ADAMTS12 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV61264723; called by muse, mutect2, varscan2
- ADAMTS16 | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs888372118, COSV56992348; called by muse, mutect2, varscan2
- ADAMTS18 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865821391, COSV51410950; called by muse, mutect2, varscan2
- ADAMTS19 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50753275; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | catalogued as rs747024597, COSV52816952; called by muse, mutect2, varscan2
- ADCY8 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53910983; called by muse, mutect2, varscan2
- ADGRB3 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1197657726, COSV53232994; called by muse, mutect2, varscan2
- ADGRD1 | c.2151del p.A718Pfs*17 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | catalogued as COSV55437404; called by mutect2, pindel, varscan2
- ADGRE2 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59693967; called by muse, mutect2, varscan2
- ADGRF5 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV51934881; called by muse, mutect2, varscan2
- ADGRG7 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1442569635, COSV56295349, COSV56297369; called by muse, mutect2, varscan2
- ADH1B | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV59295234; called by muse, mutect2, varscan2
- AGBL5 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV59936657; called by muse, mutect2, varscan2
- AKR1C4 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV54123578; called by muse, mutect2, varscan2
- ALMS1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52511521; called by muse, mutect2, varscan2
- ALPK2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV64493648; called by muse, mutect2, varscan2
- ALPL | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as CM983416, COSV100876272; called by muse, mutect2, varscan2
- ANGPT1 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52442537; called by muse, varscan2
- ANK2 | c.3982G>A p.A1328T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868750741, COSV52164809; called by muse, mutect2, varscan2
- ANK3 | c.12673C>T p.R4225* (on ENST00000280772 / NM_001320874.2; = p.R849* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV55047406; called by muse, mutect2, varscan2
- ANK3 | c.11329G>A p.E3777K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV55061346; called by muse, mutect2, varscan2
- ANK3 | c.9257G>A p.G3086E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.07); catalogued as rs866679919, COSV55061356; called by muse, mutect2, varscan2
- ANK3 | c.7097C>T p.S2366F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as rs765137118, COSV55061365; called by muse, mutect2, varscan2
- ANK3 | c.2747C>T p.S916F (on ENST00000280772 / NM_001320874.2; = p.S50F on NM_001149.3) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs750432488, COSV55049729; called by muse, mutect2, varscan2
- ANKRD44 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV56556790; called by muse, mutect2, varscan2
- ANKS4B | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100289877; called by muse, mutect2, varscan2
- ANPEP | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55592021; called by muse, mutect2, varscan2
- ANTKMT | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1441808324, COSV53496564; called by muse, mutect2, varscan2
- APC | c.3815C>T p.S1272L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD106449, CM040676, COSV57348860, COSV57351844, COSV57380973; called by muse, mutect2, varscan2
- APC2 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.07); catalogued as COSV52019222; called by muse, mutect2, varscan2
- APCDD1 | c.586T>A p.C196S | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV62372603; called by muse, mutect2, varscan2
- APOB | c.9064G>A p.D3022N | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51937685, COSV51938290; called by muse, mutect2, varscan2
- APOH | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1335081795, COSV52773003; called by muse, mutect2, varscan2
- ARHGAP21 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57606472; called by muse, mutect2, varscan2
- ARHGAP29 | c.3035G>A p.R1012K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53112687; called by muse, mutect2, varscan2
- ARHGAP44 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52395186; called by muse, mutect2, varscan2
- ARHGEF15 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62725407, COSV62725411; called by muse, mutect2, varscan2
- ARHGEF37 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781049357, COSV61368914; called by muse, mutect2, varscan2
- ARL6IP1 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.145); catalogued as COSV58614199, COSV58614483; called by muse, mutect2, varscan2
- ARSF | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100839545; called by muse, mutect2, varscan2
- ARVCF | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs762879311, COSV52889234; called by muse, mutect2, varscan2
- ASB5 | c.388A>C p.N130H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56671540; called by muse, mutect2, varscan2
- ASIP | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100892074, COSV66588414; called by muse, mutect2, varscan2
- ASPSCR1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201786107, COSV60729183; called by muse, mutect2, varscan2
- ATF6B | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 46/196 reads (23%) | catalogued as COSV64351991; called by muse, mutect2, varscan2
- ATG4A | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58965898; called by muse, mutect2, varscan2
- ATP10A | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63518366; called by muse, mutect2, varscan2
- ATP11A | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV52113413; called by muse, mutect2, varscan2
- ATP1A3 | c.382C>T p.P128S (on ENST00000545399 / NM_001256214.2; = p.P115S on NM_152296.5) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV57488163; called by muse, mutect2, varscan2
- ATP1A3 | c.136G>A p.E46K (on ENST00000545399 / NM_001256214.2; = p.E33K on NM_152296.5) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV57488169; called by muse, mutect2, varscan2
- ATP2B2 | c.2851C>T p.Q951* (on ENST00000352432; = p.Q917* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV59498067; called by muse, mutect2, varscan2
- ATP2B4 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147313187; called by muse, mutect2, varscan2
- ATP2C2 | c.1235A>T p.Q412L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV52296868; called by muse, mutect2, varscan2
- B3GALNT2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100010496; called by muse, mutect2, varscan2
- B4GALNT3 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56753154; called by muse, mutect2, varscan2
- BBOF1 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV58222217; called by muse, mutect2, varscan2
- BBS10 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV53883617; called by muse, mutect2, varscan2
- BCAN | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100228270; called by muse, mutect2, varscan2
- BCAS1 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65086716; called by muse, mutect2, varscan2
- BCL10 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV65353882; called by muse, mutect2, varscan2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by muse, mutect2, varscan2
- BMP10 | c.503T>G p.F168C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV54895508; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMP5 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV63703778, COSV63705928; called by muse, mutect2, varscan2
- BRD9 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51320279; called by muse, varscan2
- C2orf42 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52450572; called by muse, mutect2, varscan2
- C2orf80 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV100378500; called by muse, mutect2, varscan2
- C6 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs868229123, COSV54711348; called by muse, mutect2, varscan2
- C7 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs372012422; called by muse, mutect2
- C7 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV100496749, COSV57473533; called by muse, mutect2, varscan2
- C7 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs768012615; called by muse, varscan2
- C8orf34 | c.766-1G>A p.X256_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV61381987; called by muse, mutect2, varscan2
- C8orf34 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs866537511, COSV100445809, COSV61381992; called by muse, mutect2, varscan2
- CACNA1H | c.2322G>A p.W774* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1451924937, COSV61984016; called by muse, mutect2
- CACNA1I | c.5795C>T p.P1932L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV60810263; called by muse, mutect2, varscan2
- CACNG3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs868272395, COSV50063799; called by muse, mutect2, varscan2
- CADM1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59006030, COSV59012333; called by muse, mutect2, varscan2
- CADM2 | c.755G>A p.G252E (on ENST00000407528 / NM_001167674.2; = p.G254E on NM_153184.4) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67357577; called by muse, mutect2, varscan2
- CADM3 | c.245G>A p.R82Q (on ENST00000368125 / NM_001127173.3; = p.R116Q on NM_021189.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684047, COSV63685846; called by muse, mutect2, varscan2
- CADM3 | c.578C>T p.S193L (on ENST00000368125 / NM_001127173.3; = p.S227L on NM_021189.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.455); catalogued as rs1179781491, COSV63683490; called by muse, mutect2, varscan2
- CADPS | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51882892, COSV99338467; called by muse, mutect2
- CALR3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs143334090; called by muse, mutect2, varscan2
- CAMK1D | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.279); catalogued as rs201893185, COSV66612603; called by muse, mutect2, varscan2
- CAP1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs758617435, COSV61223592; called by muse, mutect2, varscan2
- CAPSL | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV68437095; called by muse, mutect2, varscan2
- CARD10 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52657302; called by muse, mutect2, varscan2
- CARF | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV57547926; called by muse, mutect2, varscan2
- CASS4 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV64386725; called by muse, mutect2, varscan2
- CCDC160 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892124; called by muse, mutect2, varscan2
- CCDC178 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55766378; called by muse, mutect2, varscan2
- CCDC69 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV62599878; called by muse, mutect2, varscan2
- CCDC88A | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV55060370, COSV55062862; called by muse, mutect2, varscan2
- CCKBR | c.1029T>A p.F343L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58099265, COSV58102047; called by muse, mutect2, varscan2
- CCNB3 | c.4121C>T p.A1374V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV52074560; called by muse, mutect2, varscan2
- CD200R1L | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV68004441; called by muse, mutect2, varscan2
- CD209 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52654590; called by muse, mutect2, varscan2
- CD96 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1035836810, COSV51917150; called by muse, mutect2, varscan2
- CD96 | c.793G>A p.V265I (on ENST00000283285 / NM_198196.3; = p.V249I on NM_005816.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51917161; called by muse, mutect2, varscan2
- CDC42BPA | c.1030A>T p.S344C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV62012272; called by muse, mutect2, varscan2
- CDCA7 | c.336G>A p.M112I (on ENST00000347703 / NM_145810.3; = p.M191I on NM_031942.5) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV60720391, COSV60720596; called by muse, mutect2, varscan2
- CDH12 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101202375, COSV101202896; called by muse, varscan2
- CDH12 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1352641663, COSV101202897, COSV66441270; called by mutect2, varscan2
- CDH26 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54847745; called by muse, mutect2, varscan2
- CDH4 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV64657340; called by muse, mutect2, varscan2
- CDH4 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64657346; called by muse, mutect2, varscan2
- CDH8 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV54871412; called by muse, varscan2
- CDH8 | c.2078G>C p.G693A | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV54871431; called by muse, mutect2, varscan2
- CDYL | c.1739C>T p.S580L (on ENST00000328908 / NM_001368125.1; = p.S526L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775840808, COSV59359988; called by muse, mutect2, varscan2
- CERS3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs770150152, COSV52569417; called by muse, mutect2, varscan2
- CES3 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57593850; called by muse, mutect2, varscan2
- CETN2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs927332703, COSV100938690, COSV64744164; called by muse, mutect2, varscan2
- CFAP45 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63649324; called by muse, varscan2
- CFAP46 | c.7096C>T p.R2366C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762502431, COSV54153367; called by muse, mutect2, varscan2
- CFAP47 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364476260, COSV52885634; called by muse, mutect2
- CFAP54 | c.7198C>T p.H2400Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.253); catalogued as COSV61572518; called by muse, mutect2, varscan2
- CFAP58 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57212343; called by mutect2, varscan2
- CFAP65 | c.4979C>A p.S1660Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.655); catalogued as COSV100445439; called by muse, varscan2
- CFHR4 | c.1292G>A p.G431E (on ENST00000367416 / NM_001201551.2; = p.G185E on NM_006684.5) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV52229902; called by muse, mutect2, varscan2
- CGNL1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55564772; called by muse, mutect2, varscan2
- CHAMP1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as rs1050189129, COSV63522496; called by muse, mutect2, varscan2
- CHD2 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV67710114; called by muse, mutect2, varscan2
- CHD5 | c.3548C>T p.S1183F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52416102; called by muse, mutect2, varscan2
- CHD8 | c.6698G>T p.S2233I (on ENST00000646647 / NM_001170629.2; = p.S1954I on NM_020920.4) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV63036929; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHRD | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52608874; called by muse, mutect2, varscan2
- CHRD | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.358); catalogued as rs1340886663, COSV52608899; called by muse, mutect2
- CHRDL1 | c.539G>A p.W180* (on ENST00000372045; = p.W186* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as COSV54325756, COSV99488026; called by muse, mutect2, varscan2
- CIT | c.4375G>A p.G1459R | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55871136; called by muse, mutect2, varscan2
- CLDN4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52895178, COSV52896081; called by muse, mutect2, varscan2
- CLEC6A | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65986728; called by muse, mutect2, varscan2
- CLEC6A | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs768668679, COSV65987417, COSV65987904; called by muse, mutect2, varscan2
- CLSPN | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as COSV52051957; called by muse, mutect2, varscan2
- CLSTN1 | c.2308G>T p.E770* (on ENST00000377298 / NM_001009566.3; = p.E760* on NM_014944.4) | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV63648531; called by muse, mutect2, varscan2
- CLVS1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV57975913; called by muse, mutect2, varscan2
- CNGA1 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.921); catalogued as COSV100652271; called by muse, mutect2, varscan2
- CNGA2 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as COSV61703983; called by muse, mutect2, varscan2
- CNMD | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65033191; called by muse, mutect2, varscan2
- CNTN2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV59350395; called by muse, mutect2
- CNTN6 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs867948020, COSV63170803; called by muse, mutect2, varscan2
- CNTNAP5 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV70489274; called by muse, mutect2, varscan2
- COBL | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.116); catalogued as rs941400845, COSV54357982; called by muse, mutect2, varscan2
- COL10A1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54573253; called by muse, mutect2, varscan2
- COL11A2 | c.2221G>A p.D741N (on ENST00000341947 / NM_080680.3; = p.D634N on NM_080679.2) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59497743; called by muse, varscan2
- COL19A1 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752857777, COSV59575112; called by muse, mutect2, varscan2
- COL22A1 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV57340026; called by muse, mutect2, varscan2
- COL2A1 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs148350640, COSV61527431; called by muse, mutect2, varscan2
- COL4A1 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs866736103, COSV65426909; called by muse, varscan2
- COL4A4 | c.4393G>A p.G1465S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV61632857; called by muse, varscan2
- COL4A4 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632862; called by muse, mutect2, varscan2
- COL5A2 | c.4100A>G p.N1367S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV66410400; called by muse, mutect2, varscan2
- COL5A2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs747140485, COSV66410403; called by muse, mutect2, varscan2
- COL5A3 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757346625, COSV53412006; called by muse, mutect2, varscan2
- COL6A2 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs779287707, COSV56006937; called by muse, mutect2, varscan2
- COL6A6 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62026983; called by muse, mutect2, varscan2
- COMMD10 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV57237251; called by muse, mutect2, varscan2
- COQ7 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746195092, COSV58981392; called by muse, mutect2, varscan2
- CPE | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV68580683; called by muse, mutect2, varscan2
- CPNE5 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs142540878; called by muse, varscan2
- CPSF3 | c.1814T>C p.L605S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV53009071; called by muse, mutect2, varscan2
- CRB1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as rs564754426, COSV66328611; called by muse, mutect2, varscan2
- CREB3L3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV50207473, COSV50221297; called by muse, mutect2, varscan2
- CRISP1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59993966; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- CRY1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745345562, COSV50490898, COSV99151015; called by muse, mutect2, varscan2
- CSMD1 | c.4361G>A p.G1454E (on ENST00000520002; = p.G1453E on NM_033225.6) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100147680, COSV59333064; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CSRNP3 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58779283; called by muse, mutect2, varscan2
- CSRNP3 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as rs764857487, COSV58777436; called by muse, mutect2, varscan2
- CTAGE1 | c.1860G>A p.M620I | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV66943689; called by muse, mutect2, varscan2
- CTCFL | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54775213; called by muse, mutect2, varscan2
- CTNNA2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58155619; called by muse, mutect2, varscan2
- CYP1B1 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs72549379, CM004520, COSV52225697; called by muse, mutect2, varscan2
- CYP26B1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV99134711; called by muse, mutect2, varscan2
- CYP27A1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51468490; called by muse, mutect2, varscan2
- CYP2C9 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as COSV53247437; called by muse, mutect2, varscan2
- CYP4F11 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56127392; called by muse, mutect2, varscan2
- DACH1 | c.1936G>A p.E646K (on ENST00000619232 / NM_001366712.1; = p.E392K on NM_004392.6) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1179043824, COSV57503001; called by muse, mutect2, varscan2
- DCC | c.1596A>T p.E532D | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.707); catalogued as COSV59106737; called by muse, mutect2, varscan2
- DCC | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV59104175; called by muse, mutect2, varscan2
- DCDC1 | c.3674A>G p.N1225S (on ENST00000597505 / NM_001367979.1; = p.N332S on NM_020869.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as rs1225049765, COSV57999669; called by muse, mutect2, varscan2
- DCLK3 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69363385; called by muse, mutect2, varscan2
- DDC | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1361553663, COSV100779824, COSV63565455; called by muse, mutect2, varscan2
- DDX17 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 40/83 reads (48%) | catalogued as COSV53253109; called by muse, mutect2, varscan2
- DGKI | c.2912A>C p.N971T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV55953494; called by muse, mutect2, varscan2
- DHX57 | c.3128T>C p.L1043S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54886086; called by muse, mutect2, varscan2
- DLG1 | c.2645A>G p.N882S (on ENST00000419354 / NM_001290983.1; = p.N904S on NM_004087.2) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV58383971; called by muse, mutect2, varscan2
- DMBT1 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1202555295, COSV57546099; called by muse, mutect2, varscan2
- DMBT1 | c.6319C>T p.R2107C (on ENST00000338354 / NM_001377530.1; = p.R1350C on NM_004406.3) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs747972203, COSV57544508; called by muse, mutect2, varscan2
- DMD | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV55876356; called by muse, mutect2, varscan2
- DNAH11 | c.11575G>A p.E3859K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100177923, COSV60957746; called by muse, mutect2, varscan2
- DNAH2 | c.9833G>A p.R3278Q | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66720542; called by muse, mutect2, varscan2
- DNAH7 | c.8087C>T p.S2696F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56768015; called by muse, mutect2, varscan2
- DNAH7 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766259116, COSV56768023; called by muse, mutect2, varscan2
- DNAH7 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs770136619, COSV56768039; called by muse, mutect2, varscan2
- DNAH8 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59451715; called by muse, mutect2, varscan2
- DNAH8 | c.10343G>A p.G3448E | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV59451740; called by muse, mutect2, varscan2
- DNAH9 | c.4198G>A p.D1400N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV99306750; called by muse, mutect2, varscan2
- DNAH9 | c.11909C>T p.T3970I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1466885283, COSV52353236, COSV52384955; called by muse, mutect2
- DNAI3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV54003034; called by muse, mutect2, varscan2
- DNAI4 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV64022236; called by muse, mutect2, varscan2
- DNAL1 | c.312T>A p.F104L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100225852; called by muse, mutect2, varscan2
- DOCK8 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV66634264; called by muse, mutect2, varscan2
- DPYD | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100929374, COSV64599655; called by muse, mutect2, varscan2
- DPYS | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs368802826; called by muse, mutect2, varscan2
- DPYSL5 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56512881; called by muse, mutect2, varscan2
- DRC1 | c.1920G>A p.R640= | Splice Region (SNP) | VAF 23/66 reads (35%) | catalogued as COSV55505305; called by muse, varscan2
- DSC1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs868027272, COSV57146410; called by muse, mutect2, varscan2
- DSCAM | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.926); catalogued as COSV68641068; called by muse, mutect2, varscan2
- DSCAML1 | c.5986A>T p.T1996S (on ENST00000321322; = p.T1936S on NM_020693.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs1207320908, COSV58392310; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSP | c.7241G>A p.G2414E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65790969, COSV65792284; called by muse, mutect2, varscan2
- DTL | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65342518; called by muse, mutect2, varscan2
- DTNBP1 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV100160948; called by muse, mutect2, varscan2
- DUSP16 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53807899; called by muse, mutect2, varscan2
- DYSF | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1325478046, COSV50417986; called by muse, mutect2, varscan2
- DYSF | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770135312, COSV50419837; called by muse, mutect2, varscan2
- EDDM3A | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs199609364, COSV58795019; called by muse, mutect2, varscan2
- EFNA2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV53065475, COSV99288991; called by muse, mutect2
- EIF2AK2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as COSV99240810; called by muse, mutect2, varscan2
- EIF3A | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs754819756, COSV64961702; called by muse, mutect2, varscan2
- ELF5 | c.610C>T p.R204W (on ENST00000312319 / NM_198381.2; = p.R194W on NM_001422.4) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759245139, COSV56629071; called by muse, mutect2, varscan2
- ENAH | c.1343T>C p.M448T | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52868632; called by muse, mutect2, varscan2
- ENTHD1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV57320926; called by muse, mutect2, varscan2
- EPHA4 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.771); catalogued as COSV56035009; called by muse, mutect2, varscan2
- EPHA6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67557029, COSV67575552; called by muse, mutect2, varscan2
- EPHA7 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV65177989; called by muse, mutect2, varscan2
- EPN2 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV59061541; called by muse, mutect2, varscan2
- ERBB4 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61493352; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by muse, mutect2, varscan2
- ERN1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV70502531; called by muse, mutect2, varscan2
- ESRRB | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV55062474; called by muse, mutect2, varscan2
- ETFB | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58536217; called by muse, mutect2, varscan2
- EXTL3 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1288613234, COSV55038333; called by muse, mutect2, varscan2
- EYA4 | c.1097C>T p.P366L (on ENST00000531901 / NM_001301013.1; = p.P360L on NM_004100.5) | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV62053314; called by muse, varscan2
- EYS | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV60979099; called by muse, mutect2, varscan2
- FAM126A | c.1563T>A p.D521E | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV69471853; called by muse, mutect2, varscan2
- FAM135B | c.2982T>A p.H994Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV52729555; called by muse, varscan2
- FAM135B | c.2854G>A p.G952S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1343882297, COSV52716866; called by muse, varscan2
- FAM13C | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV53249677; called by muse, mutect2, varscan2
- FAM155A | c.1088-1G>A p.X363_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV65558768; called by mutect2, varscan2
- FAM170A | c.984G>A p.R328= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FAM181A | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV50889058; called by muse, mutect2, varscan2
- FAM193A | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs913170203, COSV61194791; called by muse, mutect2, varscan2
- FAM227B | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV54812246; called by muse, mutect2, varscan2
- FAM234B | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52194983, COSV52195638; called by muse, mutect2, varscan2
- FAM3D | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.303); catalogued as COSV62558477; called by muse, mutect2, varscan2
- FAM47C | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100792216, COSV63727084; called by muse, mutect2, varscan2
- FAM47C | c.2729A>T p.K910I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV63727092; called by muse, mutect2, varscan2
- FAM83B | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV60922749, COSV60928099; called by muse, mutect2, varscan2
- FAM90A1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56712552; called by muse, mutect2, varscan2
- FAT1 | c.10111C>T p.H3371Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as COSV71674454; called by muse, mutect2
- FAT3 | c.8578G>A p.E2860K | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs765949446, COSV53120309; called by muse, mutect2, varscan2
- FAT4 | c.8206G>A p.E2736K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58689044; called by muse, mutect2, varscan2
- FAT4 | c.13546A>G p.T4516A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58689062; called by muse, mutect2, varscan2
- FBH1 | c.2032T>A p.Y678N (on ENST00000362091 / NM_178150.3; = p.Y729N on NM_032807.4) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62982833; called by muse, mutect2, varscan2
- FBN2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1561427124, COSV52518076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138440561; called by muse, mutect2, varscan2
- FBXL2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as COSV52139393, COSV52141324; called by muse, mutect2, varscan2
- FBXO38 | c.3189A>T p.E1063D (on ENST00000340253 / NM_205836.3; = p.E988D on NM_030793.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57028327; called by muse, mutect2, varscan2
- FCN1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs1237445092, COSV65662486; called by muse, mutect2, varscan2
- FCN3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV54641545; called by muse, mutect2, varscan2
- FEN1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57250927; called by muse, mutect2, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, mutect2, varscan2
- FHOD3 | c.2597C>T p.P866L (on ENST00000359247 / NM_001281739.3; = p.P883L on NM_025135.5) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs372094507; called by muse, mutect2, varscan2
- FKBP6 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52720553; called by muse, mutect2, varscan2
- FLG | c.5666C>T p.S1889F | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64235764; called by muse, varscan2
- FLG | c.3002G>A p.S1001N | Missense Mutation (SNP) | VAF 99/385 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1476358212, COSV64242718; called by muse, varscan2
- FLG2 | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV66169260; called by muse, mutect2, varscan2
- FLG2 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV66169266; called by muse, varscan2
- FLG2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66169271; called by muse, mutect2, varscan2
- FLT4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs139272488; called by muse, mutect2, varscan2
- FOXG1 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV57397169; called by muse, mutect2, varscan2
- FOXN1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV56882177; called by muse, mutect2, varscan2
- FRA10AC1 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV63272388; called by muse, mutect2
- FRMPD4 | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769362466, COSV66216153; called by muse, mutect2, varscan2
- FSHR | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58635603; called by muse, mutect2, varscan2
- FTCD | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as COSV52426152; called by muse, mutect2, varscan2
- FTHL17 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100784357, COSV63267036; called by muse, mutect2, varscan2
- GAB3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65819167; called by muse, mutect2, varscan2
- GABPB2 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as COSV64460974, COSV64461191; called by muse, mutect2, varscan2
- GABRA1 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV50104820, COSV99196077; called by muse, mutect2, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, varscan2
- GABRA3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV64799747; called by muse, mutect2, varscan2
- GABRA3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750973085, COSV64795435; called by muse, mutect2, varscan2
- GABRA4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV51929054; called by muse, mutect2, varscan2
- GAGE10 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV68163942; called by muse, mutect2, varscan2
- GALNT1 | c.1231T>C p.F411L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52452726; called by muse, mutect2, varscan2
- GALNT14 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61105953; called by muse, mutect2, varscan2
- GALNT17 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61165373; called by muse, mutect2, varscan2
- GALNT6 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as rs774059724, COSV62542406; called by muse, mutect2, varscan2
- GAPT | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs370924428; called by muse, mutect2, varscan2
- GC | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.387); catalogued as rs866866487, COSV56737720; called by muse, mutect2, varscan2
- GCM2 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1443437817, COSV65275780; called by muse, mutect2, varscan2
- GEM | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs567967510, COSV52597636; called by muse, mutect2, varscan2
- GFAP | c.972T>G p.Y324* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs767003792, COSV53651122; called by muse, mutect2, varscan2
- GFRAL | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 54/153 reads (35%) | catalogued as COSV61231500, COSV61234830; called by muse, mutect2, varscan2
- GHITM | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100930107; called by muse, mutect2, varscan2
- GIMAP2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56235471; called by muse, mutect2, varscan2
- GIPC3 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100461412; called by muse, mutect2, varscan2
- GIT2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1246072432, COSV58081328; called by muse, mutect2, varscan2
- GLDN | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV59090554; called by muse, mutect2
- GLP2R | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52325589; called by muse, mutect2, varscan2
- GLRA3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56863045; called by muse, mutect2, varscan2
- GLT6D1 | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65627837; called by muse, mutect2, varscan2
- GLT8D2 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62562090; called by muse, mutect2, varscan2
- GLYATL2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV54850179; called by muse, mutect2, varscan2
- GNB3 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51833669; called by muse, mutect2, varscan2
- GNL2 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV56170147; called by muse, mutect2, varscan2
- GOLT1A | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57643905; called by muse, mutect2, varscan2
- GPR108 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51184993, COSV51185435; called by muse, mutect2
- GPR78 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV66763182; called by muse, mutect2, varscan2
- GPRC5B | c.161T>A p.I54N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV56026852; called by muse, varscan2
- GRAMD4 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs377286272; called by muse, varscan2
- GRAMD4 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63031000; called by muse, mutect2, varscan2
- GREB1 | c.2485A>G p.I829V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52188720; called by muse, mutect2, varscan2
- GRIN2A | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV58036510; called by muse, mutect2, varscan2
- GRIN2A | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs868215122, COSV58026833; called by muse, mutect2, varscan2
- GRIN2B | c.3007C>T p.L1003F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV74206188; called by muse, mutect2, varscan2
- GRIN2B | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs942467986, COSV74206189; called by muse, mutect2, varscan2
- GRM1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs764759109, COSV51156102; called by muse, mutect2, varscan2
- GRM4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs765772360, COSV65214244; called by muse, mutect2, varscan2
- GRM7 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV63142387; called by muse, mutect2, varscan2
- GRM8 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs776640209, COSV58831156; called by muse, mutect2, varscan2
- GRPR | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66669577; called by muse, mutect2, varscan2
- GUCY2C | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV53791042; called by muse, mutect2, varscan2
- H2BC17 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV58152841; called by muse, mutect2, varscan2
- H3-5 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV61187197; called by muse, mutect2, varscan2
- HAT1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV51363046; called by muse, mutect2, varscan2
- HDAC5 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.147); catalogued as COSV52242695; called by muse, mutect2, varscan2
- HDAC9 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67774705; called by muse, mutect2, varscan2
- HECW1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV67831100; called by muse, mutect2, varscan2
- HEPHL1 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.88); PolyPhen benign (0.168); catalogued as rs1235991160, COSV59892497; called by muse, mutect2, varscan2
- HERC5 | c.1737G>A p.R579= | Splice Region (SNP) | VAF 3/22 reads (14%) | catalogued as rs1268567133; called by muse, mutect2
- HERPUD2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.425); catalogued as COSV60945474; called by muse, mutect2, varscan2
- HINFP | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.62); PolyPhen benign (0.265); catalogued as COSV63432094; called by muse, mutect2, varscan2
- HIRA | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV54272900; called by muse, mutect2, varscan2
- HLA-DQA2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as COSV66565622; called by muse, varscan2
- HLX | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV100854574; called by muse, mutect2, varscan2
- HMCN1 | c.6778G>C p.E2260Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.438); catalogued as COSV54905871; called by muse, mutect2, varscan2
- HPX | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV56419283; called by muse, mutect2, varscan2
- HROB | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55369803; called by muse, mutect2
- HSFX1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 49/402 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1439779364; called by muse, mutect2, varscan2
- HTR7 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV53286504; called by muse, mutect2, varscan2
- IFT140 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV68489338; called by muse, mutect2, varscan2
- IFT74 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV66287295; called by muse, mutect2, varscan2
- IGHV1-24 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367908320; called by muse, mutect2, varscan2
- IGHV3-49 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.141); catalogued as rs374222402; called by muse, mutect2, varscan2
- IGHV3-7 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs565443498; called by muse, mutect2
- IGLV3-27 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs570338405; called by muse, mutect2, varscan2
- IGSF10 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV56786240; called by muse, varscan2
- IGSF9 | c.1331G>A p.G444E (on ENST00000368094 / NM_001135050.2; = p.G428E on NM_020789.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63638899; called by muse, mutect2, varscan2
- IL17B | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV51002999, COSV99199163; called by muse, mutect2
- IL1RAPL2 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as COSV61161185; called by muse, mutect2, varscan2
- IL7R | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM056607, COSV57409143; called by muse, mutect2, varscan2
- INO80 | c.1012C>G p.R338G | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62738681; called by muse, mutect2, varscan2
- IRAG2 | c.4021G>A p.D1341N (on ENST00000636465; = p.D386N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV57232690; called by muse, mutect2
- IRX1 | c.679A>T p.S227C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99042692; called by muse, mutect2, varscan2
- IRX1 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.201); catalogued as rs745983655, COSV57363100; called by muse, mutect2, varscan2
- ISLR2 | c.504C>G p.D168E | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.228); catalogued as COSV62302371; called by muse, mutect2, varscan2
- ITGAL | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866967977, COSV63322541; called by muse, mutect2, varscan2
- ITGB8 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1454481851, COSV56009663; called by muse, mutect2, varscan2
- ITIH3 | c.404T>G p.L135W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69649138; called by muse, mutect2, varscan2
- ITSN2 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1284289801, COSV61948305; called by muse, mutect2, varscan2
- IZUMO4 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1235781918, COSV61429079; called by muse, mutect2, varscan2
- JARID2 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.041); catalogued as rs759363568, COSV59190548; called by mutect2, varscan2
- JCAD | c.2784G>A p.W928* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV64760010; called by muse, mutect2, varscan2
- JPH2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768672949, COSV65903480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KANK4 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV62987160; called by muse, mutect2, varscan2
- KARS1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56692551; called by muse, mutect2, varscan2
- KCNB2 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73050616; called by muse, mutect2, varscan2
- KCNH5 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs371757416; called by muse, varscan2
- KCNH6 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV59004073; called by muse, mutect2, varscan2
- KCNH7 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV59799061; called by muse, mutect2, varscan2
- KCNJ10 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100927934, COSV63635126; called by muse, mutect2, varscan2
- KCNK10 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV56645826; called by muse, varscan2
- KCNK10 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs764827922, COSV56642936; called by muse, varscan2
- KCNN3 | c.1696G>A p.A566T (on ENST00000618040 / NM_001204087.1; = p.A551T on NM_002249.6) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV55218396; called by muse, mutect2, varscan2
- KCNS2 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.089); catalogued as rs1325431545, COSV54638309; called by muse, mutect2, varscan2
- KCNT2 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV54083633; called by muse, mutect2, varscan2
- KDR | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868047715, COSV55764136; called by muse, mutect2, varscan2
- KIAA0825 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs147120237, COSV56951063; called by mutect2, varscan2
- KIAA1217 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.345); catalogued as COSV56817623; called by muse, mutect2
- KIAA1549 | c.4462C>T p.L1488F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317192989, COSV54316273; called by muse, mutect2, varscan2
- KIF14 | c.3472G>A p.G1158S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV66262033; called by muse, mutect2, varscan2
- KIF17 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs140327262; called by muse, mutect2, varscan2
- KIF1B | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV55809780; called by muse, mutect2, varscan2
- KIR2DL1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV52410457; called by muse, varscan2
- KIR3DL3 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV52548415; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KLHL1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV64767138, COSV64784452; called by muse, mutect2, varscan2
- KLHL11 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV59862154; called by muse, mutect2, varscan2
- KLHL13 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV53248744; called by muse, mutect2, varscan2
- KMT2A | c.6728T>C p.V2243A | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs139450035; called by muse, mutect2, varscan2
- KMT2C | c.7346C>T p.P2449L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51447562; called by muse, mutect2, varscan2
- KMT2D | c.16207C>T p.R5403C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56448083, COSV56495821; called by muse, mutect2, varscan2
- KNDC1 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58838844; called by muse, mutect2, varscan2
- KREMEN1 | c.1163T>C p.V388A (on ENST00000407188; = p.V390A on NM_032045.5) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV59913127; called by muse, mutect2, varscan2
- KRT15 | c.1061A>C p.E354A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54179764; called by muse, mutect2, varscan2
- KRT4 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs758257972, COSV53406308; called by muse, mutect2, varscan2
- KRT40 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV66696405; called by muse, mutect2, varscan2
- KRT71 | c.620G>C p.R207T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs778146621, COSV57290975; called by muse, mutect2, varscan2
- KRT72 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV53373724; called by muse, mutect2, varscan2
- KRT82 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs751256040, COSV99233740; called by muse, mutect2, varscan2
- L1CAM | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.251); catalogued as COSV62828450; called by muse, mutect2, varscan2
- LAIR1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV57307909; called by muse, mutect2, varscan2
- LAMA2 | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV70349156; called by muse, mutect2, varscan2
- LAMB1 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs762419153, COSV55962917; called by muse, mutect2, varscan2
- LAMB4 | c.4129G>A p.G1377R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773209011, COSV52720839, COSV52727511; called by muse, mutect2, varscan2
- LARP1 | c.2680C>T p.R894C (on ENST00000518297 / NM_033551.3; = p.R817C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60427689; called by muse, varscan2
- LCE1D | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 25/28 reads (89%) | PolyPhen probably damaging (0.996); catalogued as COSV58270677; called by muse, mutect2, varscan2
- LCT | c.3916G>A p.D1306N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489231732, COSV51544059; called by muse, mutect2, varscan2
- LGI1 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65058165; called by muse, mutect2, varscan2
- LGR5 | c.2579A>C p.Q860P | Missense Mutation (SNP) | VAF 178/369 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV57005582, COSV57009010; called by muse, mutect2, varscan2
- LILRB4 | c.1228G>A p.D410N (on ENST00000391733 / NM_001278428.3; = p.D409N on NM_001278426.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54405902; called by muse, mutect2, varscan2
- LIMCH1 | c.2367G>A p.Q789= | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as COSV58285685; called by muse, mutect2
- LIX1L | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs587659330, COSV63417133; called by muse, mutect2, varscan2
- LMAN1L | c.1200G>A p.R400= | Splice Region (SNP) | VAF 24/81 reads (30%) | catalogued as COSV59002205; called by muse, mutect2
- LPO | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1339726118, COSV51859481, COSV99228204; called by muse, mutect2, varscan2
- LRBA | c.1588T>A p.Y530N | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV63956684; called by muse, mutect2, varscan2
- LRP2 | c.4109G>A p.G1370E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55556675; called by muse, mutect2, varscan2
- LRRC15 | c.1526C>T p.T509I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV61650314; called by muse, mutect2
- LRRC3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52399474; called by muse, varscan2
- LRRC30 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV101274367; called by muse, mutect2, varscan2
- LRRC40 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs760500758, COSV63942461; called by muse, mutect2, varscan2
- LTBP1 | c.1964G>A p.G655E (on ENST00000404816 / NM_206943.4; = p.G329E on NM_000627.4) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63188828; called by muse, mutect2, varscan2
- LUM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV57127963; called by muse, mutect2, varscan2
- LUZP2 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100418560, COSV61206627; called by muse, mutect2
- LVRN | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs1159775656, COSV63497415; called by muse, mutect2, varscan2
- LVRN | c.1407T>A p.N469K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV63497419; called by muse, mutect2, varscan2
- LVRN | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs369575731; called by muse, mutect2, varscan2
- LY75 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99716670; called by muse, mutect2, varscan2
- MAB21L4 | c.665G>A p.G222E (on ENST00000388934 / NM_001085437.3; = p.G54E on NM_024861.4) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV100278587; called by muse, mutect2, varscan2
- MAB21L4 | c.664G>A p.G222R (on ENST00000388934 / NM_001085437.3; = p.G54R on NM_024861.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs199996891, COSV100278590; called by muse, mutect2, varscan2
- MAGEA10 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs1240123036, COSV54882680; called by muse, mutect2, varscan2
- MAGEC3 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV53581324; called by muse, mutect2, varscan2
- MAP10 | c.2300T>A p.I767N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV69363809; called by muse, mutect2, varscan2
- MAP3K13 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV53989861; called by muse, mutect2, varscan2
- MAP3K15 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs755192127, COSV58831256; called by muse, mutect2, varscan2
- MAP3K5 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as rs78303756, COSV62889847; called by muse, mutect2, varscan2
- MAP7D1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60216659; called by muse, mutect2, varscan2
- MAPKBP1 | c.4388C>T p.S1463L (on ENST00000456763 / NM_001128608.2; = p.S1457L on NM_014994.3) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52962480; called by muse, mutect2, varscan2
- MARK1 | c.2230C>T p.H744Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV65067980; called by muse, mutect2, varscan2
- MBD5 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs866370990, COSV68697354; called by muse, mutect2, varscan2
- MBL2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.407); catalogued as rs765762469, COSV64758675; called by muse, mutect2, varscan2
- MBOAT7 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV55476085; called by muse, mutect2, varscan2
- MCOLN2 | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV52296296; called by muse, mutect2, varscan2
- MECOM | c.2668G>A p.D890N (on ENST00000468789 / NM_001105078.4; = p.D1078N on NM_004991.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV52965862; called by muse, mutect2, varscan2
- MECOM | c.718G>A p.E240K (on ENST00000468789 / NM_001105078.4; = p.E428K on NM_004991.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52964419; called by muse, mutect2, varscan2
- MECOM | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761171278, COSV72110504; called by muse, mutect2, varscan2
- MED24 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV62418971; called by muse, mutect2, varscan2
- MEPE | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV63073022; called by muse, mutect2, varscan2
- METTL17 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV53869805; called by muse, mutect2, varscan2
- MGAM | c.4976C>T p.A1659V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs753276772, COSV101527810, COSV72074781; called by muse, mutect2, varscan2
- MGAT4C | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770702724, COSV59832815, COSV59833353; called by muse, mutect2, varscan2
- MIB1 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.678); catalogued as COSV55089647, COSV55091192; called by muse, mutect2, varscan2
- MID1 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs868016081, COSV58195302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIIP | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV52427844; called by muse, mutect2, varscan2
- MLLT10 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56996976; called by muse, mutect2, varscan2
- MMP16 | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54168692; called by muse, mutect2, varscan2
- MMP17 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV62179649; called by muse, mutect2, varscan2
- MN1 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV56557356; called by muse, mutect2, varscan2
- MORC1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51721449; called by muse, mutect2, varscan2
- MPHOSPH8 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as rs377735940; called by muse, mutect2, varscan2
- MR1 | c.969G>A p.W323* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV51581046; called by muse, mutect2, varscan2
- MROH2B | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68184920; called by muse, mutect2, varscan2
- MTCL1 | c.4649C>T p.P1550L (on ENST00000306329 / NM_001378206.1; = p.P1231L on NM_015210.4) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1221825659, COSV60406839; called by muse, mutect2, varscan2
- MTMR11 | c.1336C>T p.Q446* (on ENST00000439741 / NM_001145862.2; = p.Q374* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99641265; called by muse, mutect2, varscan2
- MUC16 | c.31921C>T p.P10641S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV67470923; called by muse, varscan2
- MUC16 | c.31808C>T p.P10603L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV67470930; called by muse, varscan2
- MUC16 | c.15094C>T p.P5032S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV67470979; called by muse, mutect2, varscan2
- MUC16 | c.14425G>A p.D4809N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.181); catalogued as rs1186284533, COSV67470987; called by muse, mutect2, varscan2
- MUC3A | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious, low confidence (0.03); catalogued as COSV100114919; called by muse, mutect2, varscan2
- MUC3A | c.7694C>T p.S2565F | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV60216026; called by muse, mutect2, varscan2
- MXRA5 | c.5312G>A p.R1771K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV54237821; called by muse, mutect2, varscan2
- MYBPC1 | c.1807A>T p.N603Y (on ENST00000550270 / NM_206820.2; = p.N628Y on NM_002465.4) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62253617; called by muse, mutect2, varscan2
- MYF6 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV57352056; called by muse, mutect2, varscan2
- MYH1 | c.5005G>T p.E1669* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56849786; called by muse, mutect2, varscan2
- MYH1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV56844122; called by muse, mutect2, varscan2
- MYH1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56849811; called by muse, mutect2, varscan2
- MYH1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs753684645, COSV56849820; called by muse, mutect2, varscan2
- MYH11 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs998492066, COSV55555581; called by muse, mutect2, varscan2
- MYH13 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs371327620; called by muse, mutect2, varscan2
- MYH4 | c.5413G>A p.E1805K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55119387; called by muse, mutect2, varscan2
- MYH6 | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182951502, COSV62449457; called by muse, mutect2, varscan2
- MYH7 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV62519987; called by muse, mutect2, varscan2
- MYH8 | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765916450, COSV67966297; called by muse, mutect2, varscan2
- MYLK | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100659296; called by muse, mutect2, varscan2
- MYLK | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as rs764449392, COSV60611960; called by muse, varscan2
- MYO10 | c.5998C>T p.L2000F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV57022887; called by muse, mutect2, varscan2
- MYO3B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331334030, COSV58705094; called by muse, mutect2, varscan2
- MYO7B | c.2320C>T p.L774F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV67348379, COSV67348812; called by muse, mutect2, varscan2
- MYRF | c.1276C>T p.L426F (on ENST00000278836 / NM_001127392.3; = p.L417F on NM_013279.4) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53889538; called by muse, mutect2, varscan2
- NAA25 | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99927782; called by muse, mutect2, varscan2
- NALCN | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1303333396, COSV51939992; called by muse, mutect2, varscan2
- NBEA | c.7778T>C p.F2593S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV59790010; called by muse, mutect2, varscan2
- NBPF3 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs749385030, COSV59059797; called by muse, mutect2, varscan2
- NCKAP5 | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as COSV58447958; called by muse, mutect2, varscan2
- NCOA5 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs774800618, COSV51643360; called by muse, mutect2, varscan2
- NEB | c.18755G>A p.G6252E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV51422875; called by muse, mutect2, varscan2
- NF1 | c.2351G>A p.W784* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as CM143338, COSV62209814; called by mutect2, varscan2
- NFAT5 | c.3697C>T p.Q1233* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV63028115; called by muse, mutect2, varscan2
- NFIA | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63608684; called by muse, mutect2, varscan2
- NFRKB | c.2165C>T p.P722L (on ENST00000446488 / NM_001143835.2; = p.P747L on NM_006165.3) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.141); catalogued as COSV58758422; called by muse, mutect2, varscan2
- NFU1 | c.230G>A p.G77E (on ENST00000410022 / NM_001002755.4; = p.G53E on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753296467, COSV100361239; called by muse, mutect2, varscan2
- NFU1 | c.229G>A p.G77R (on ENST00000410022 / NM_001002755.4; = p.G53R on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100361259; called by muse, mutect2, varscan2
- NFXL1 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV61199280; called by muse, mutect2, varscan2
- NIN | c.4936C>G p.R1646G (on ENST00000382041 / NM_182946.1; = p.R933G on NM_016350.4) | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV55387638, COSV55393332; called by muse, mutect2, varscan2
- NLGN4X | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV52021445; called by muse, varscan2
- NLRP12 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV60748663; called by muse, mutect2, varscan2
- NLRP3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100276344; called by muse, mutect2, varscan2
- NLRP3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307114721, COSV100276347, COSV60228184; called by muse, mutect2
- NOS1 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV57613926; called by muse, mutect2, varscan2
- NOX5 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756965311, COSV52986037, COSV99533727; called by muse, mutect2, varscan2
- NPTXR | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60728484; called by muse, mutect2, varscan2
- NR1H4 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); catalogued as COSV51852756; called by muse, mutect2, varscan2
- NR3C1 | c.1397A>C p.D466A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51543399; called by muse, mutect2, varscan2
- NRP2 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55929544; called by muse, mutect2, varscan2
- NSUN6 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 38/59 reads (64%) | catalogued as COSV66033586; called by muse, mutect2, varscan2
- NTN5 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1015357976, COSV54307546; called by muse, mutect2, varscan2
- NUDT13 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV61968977; called by muse, mutect2, varscan2
- NUP133 | c.2045A>G p.N682S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1346813375, COSV54572134; called by muse, mutect2, varscan2
- NUP133 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV54569053, COSV54572148; called by muse, mutect2, varscan2
- NUP210 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs1026389606, COSV54403879; called by muse, mutect2
- NXPH3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV60872280; called by muse, mutect2, varscan2
- OGDHL | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV65100611; called by muse, mutect2, varscan2
- OOSP2 | c.258A>C p.E86D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1353185891, COSV53929026; called by muse, mutect2, varscan2
- OPRK1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200955469, COSV55568128, COSV55571145; called by muse, mutect2, varscan2
- OR10A7 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs769774361, COSV58278742; called by muse, mutect2, varscan2
- OR10AG1 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV56633199; called by muse, mutect2, varscan2
- OR10C1 | c.613G>A p.A205T (on ENST00000622521; = p.A203T on NM_013941.3) | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV65822432, COSV65823074; called by muse, mutect2, varscan2
- OR10H1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV100612423, COSV58471652; called by muse, mutect2, varscan2
- OR10J3 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV59954473; called by muse, mutect2, varscan2
- OR1B1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.458); catalogued as rs1353921241, COSV59171854; called by muse, mutect2, varscan2
- OR1D2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58920962; called by muse, mutect2, varscan2
- OR1M1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70036972; called by muse, mutect2, varscan2
- OR2B3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65850766; called by muse, mutect2, varscan2
- OR2G3 | c.531T>G p.F177L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV60681925; called by muse, mutect2, varscan2
- OR2H2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV63542777; called by muse, mutect2
- OR2L13 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV63553993, COSV63559525; called by muse, mutect2, varscan2
- OR2M7 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58738172, COSV58738358; called by muse, mutect2, varscan2
- OR4K13 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV59859801; called by muse, mutect2, varscan2
- OR4K2 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53848458, COSV53850867; called by muse, mutect2, varscan2
- OR52K2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as rs369240508; called by muse, mutect2, varscan2
- OR5AS1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV57982036; called by muse, mutect2, varscan2
- OR5B17 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as COSV62160408; called by muse, mutect2, varscan2
- OR5M8 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59117013; called by muse, mutect2, varscan2
- OR6B3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV60112618, COSV60114301; called by muse, mutect2, varscan2
- OR7A10 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); catalogued as COSV50166408; called by muse, mutect2, varscan2
- OR8B12 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV60911884; called by muse, mutect2, varscan2
- OR9A4 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71885543; called by muse, mutect2, varscan2
- OR9G1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV56451004; called by muse, mutect2, varscan2
- OTOGL | c.5030C>T p.S1677F (on ENST00000547103; = p.S1668F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs755374459, COSV54017686; called by muse, mutect2, varscan2
- OVGP1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs765320156, COSV63858591; called by muse, mutect2, varscan2
- PAK5 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 109/147 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140682624, COSV62029174; called by muse, mutect2, varscan2
- PAPPA2 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs748663784, COSV62778150, COSV62778844; called by muse, mutect2, varscan2
- PARD3B | c.2264C>T p.A755V (on ENST00000406610 / NM_001302769.2; = p.A693V on NM_152526.6) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62514090; called by muse, mutect2, varscan2
- PARM1 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100268759, COSV56654375; called by muse, mutect2, varscan2
- PCDHA1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65372743; called by muse, mutect2, varscan2
- PCDHA11 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782773688, COSV56508681; called by muse, mutect2, varscan2
- PCDHA13 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782445481, COSV56508714; called by muse, mutect2, varscan2
- PCDHB14 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.117); catalogued as rs782175701, COSV53386728; called by muse, varscan2
- PCDHB3 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564152; called by muse, mutect2, varscan2
- PCDHB4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as COSV52023242; called by muse, mutect2, varscan2
- PCDHB8 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782362169, COSV99176242; called by muse, mutect2, varscan2
- PCDHGA10 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53961997; called by muse, mutect2, varscan2
- PCDHGA3 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53961917; called by muse, mutect2, varscan2
- PCDHGA4 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53961956; called by muse, varscan2
- PCDHGB7 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489556538, COSV53962006; called by muse, mutect2, varscan2
- PCLO | c.9574C>T p.P3192S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs761690122, COSV61639511; called by muse, mutect2, varscan2
- PCLO | c.5810G>A p.R1937Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs750274296, COSV61629961; called by muse, mutect2, varscan2
- PCNX2 | c.5788A>G p.T1930A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50809198; called by muse, mutect2, varscan2
- PCSK1 | c.2116A>T p.K706* | Nonsense Mutation (SNP) | VAF 39/124 reads (31%) | catalogued as COSV60735752; called by muse, mutect2, varscan2
- PCSK1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60735761; called by muse, mutect2, varscan2
- PCSK5 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV65089960; called by muse, mutect2, varscan2
- PCSK5 | c.2510+1G>A p.X837_splice | Splice Site (SNP) | VAF 30/60 reads (50%) | catalogued as COSV65085391; called by muse, mutect2, varscan2
- PCYT1B | c.979A>T p.S327C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV63265159; called by muse, mutect2, varscan2
- PDCD10 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868732450, COSV67102093, COSV67103181; called by muse, mutect2, varscan2
- PDE7B | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1337158102, COSV57498936; called by muse, mutect2, varscan2
- PDGFRA | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV57269030; called by muse, mutect2, varscan2
- PDHA2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776756344, COSV54778480, COSV54779576; called by muse, mutect2, varscan2
- PDK4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50010716; called by muse, mutect2, varscan2
- PDZD2 | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV56860253; called by muse, mutect2, varscan2
- PDZRN3 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV55202614; called by muse, varscan2
- PEAK1 | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as COSV56936876; called by muse, mutect2, varscan2
- PEG3 | c.2606A>T p.N869I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV55635936; called by muse, mutect2, varscan2
- PGAM2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs774216406, COSV51978441; called by mutect2, varscan2
- PHIP | c.5195C>T p.P1732L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99244481; called by muse, mutect2, varscan2
- PHIP | c.5194C>T p.P1732S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51505002; called by muse, mutect2, varscan2
- PHYKPL | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749715320, COSV57424501; called by muse, mutect2, varscan2
- PIAS3 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 62/102 reads (61%) | catalogued as COSV65171482; called by muse, mutect2, varscan2
- PIEZO2 | c.7837G>A p.D2613N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53290249, COSV53295613; called by muse, mutect2, varscan2
- PIM3 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1478151833, COSV62259726; called by muse, mutect2, varscan2
- PIWIL2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.092); catalogued as rs1437231997, COSV63251914; called by muse, mutect2, varscan2
- PKHD1L1 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs958715836, COSV65740825; called by muse, mutect2, varscan2
- PKHD1L1 | c.4373G>A p.G1458E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV65744477; called by muse, mutect2, varscan2
- PKHD1L1 | c.6768C>A p.F2256L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV65744484; called by muse, mutect2, varscan2
- PKHD1L1 | c.10066G>A p.D3356N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65737050, COSV65744498; called by muse, mutect2, varscan2
- PKHD1L1 | c.10664C>T p.P3555L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV101005220, COSV65743211; called by muse, mutect2, varscan2
- PLA1A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56331095; called by muse, mutect2, varscan2
- PLCB1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV62038366; called by muse, mutect2, varscan2
- PLCB4 | c.2949G>A p.M983I | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53798039; called by muse, mutect2, varscan2
- PLCE1 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs1199755219, COSV53353310; called by muse, mutect2, varscan2
- PLCE1 | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV53338673; called by muse, mutect2, varscan2
- PLCL2 | c.2459A>G p.N820S (on ENST00000615277 / NM_001144382.2; = p.N694S on NM_015184.5) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV67620481; called by muse, mutect2, varscan2
- PLEKHM3 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66816839; called by muse, mutect2, varscan2
- PLG | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV51983564; called by muse, mutect2, varscan2
- PLG | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV51983574; called by muse, mutect2, varscan2
- PLPPR2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99264597; called by muse, mutect2, varscan2
- PLTP | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62465013; called by muse, mutect2, varscan2
- PLXNA3 | c.4221G>A p.R1407= | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as COSV63754350; called by muse, mutect2, varscan2
- PNPLA1 | c.1493A>T p.N498I (on ENST00000394571 / NM_001374623.1; = p.N403I on NM_173676.2) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV57234864; called by muse, mutect2, varscan2
- PODNL1 | c.1514G>A p.W505* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99582740; called by muse, mutect2, varscan2
- PPEF1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs781608340, COSV62995900; called by muse, mutect2, varscan2
- PPIG | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs757114325, COSV53643632; called by muse, mutect2, varscan2
- PPP1R12B | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV61118141; called by muse, mutect2, varscan2
- PPP1R15A | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as rs148034650; called by muse, varscan2
- PPP1R21 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54285255; called by muse, mutect2, varscan2
- PPP4R4 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58555147; called by muse, mutect2, varscan2
- PRB2 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.763); catalogued as rs1565417732, COSV66982198; called by muse, mutect2, varscan2
- PRG4 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66622728; called by muse, mutect2, varscan2
- PRIMPOL | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.152); catalogued as COSV59249042; called by muse, mutect2, varscan2
- PRKAG2 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as CM066971, CM096355, COSV55231144; called by muse, mutect2, varscan2
- PRKG1 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64767295, COSV64771514; called by muse, mutect2, varscan2
- PROM2 | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.506); catalogued as COSV58298492; called by muse, mutect2, varscan2
- PRR23B | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs765732964, COSV61494033; called by muse, mutect2, varscan2
- PRRC2A | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV65687038; called by muse, mutect2, varscan2
- PRSS12 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as COSV56606805; called by muse, mutect2, varscan2
- PRSS37 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1315338000, COSV63339524; called by muse, mutect2, varscan2
- PRUNE2 | c.2993C>A p.S998* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV65042265; called by muse, mutect2, varscan2
- PSAP | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 29/60 reads (48%) | catalogued as COSV67550494; called by muse, mutect2, varscan2
- PSG1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs769714836, COSV99740679; called by muse, varscan2
- PSG2 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61545456; called by muse, mutect2, varscan2
- PSG3 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59504764, COSV59507322; called by muse, mutect2, varscan2
- PSG5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV61653914; called by muse, mutect2, varscan2
- PSMB10 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as COSV50452950; called by muse, mutect2, varscan2
- PTGFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs151178719; called by muse, mutect2, varscan2
- PTPN14 | c.3397C>T p.L1133F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65284700; called by muse, mutect2, varscan2
- PTPN21 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60848782; called by muse, mutect2, varscan2
- PTPRF | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV63445591; called by muse, mutect2, varscan2
- PTPRT | c.4145G>A p.G1382E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61959380, COSV61986293; called by muse, mutect2, varscan2
- QTRT2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99846830; called by muse, mutect2, varscan2
- RAD23A | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.061); catalogued as COSV100380184, COSV100380297; called by muse, mutect2
- RADX | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.368); catalogued as COSV100998869; called by muse, mutect2, varscan2
- RADX | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100998870; called by muse, mutect2, varscan2
- RAI14 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99463834; called by muse, mutect2, varscan2
- RAI14 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99463842; called by muse, mutect2, varscan2
- RALGPS2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61337429; called by muse, mutect2, varscan2
- RAPGEF6 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57247544; called by muse, mutect2, varscan2
- RASA2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53937999; called by muse, mutect2, varscan2
- RASEF | c.429C>T p.P143= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as COSV61551121; called by muse, mutect2, varscan2
- RBBP6 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs772826182, COSV60505623; called by muse, mutect2, varscan2
- RBL1 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV60330334; called by muse, mutect2, varscan2
- RBM26 | c.2311G>A p.A771T (on ENST00000438737 / NM_001366735.2; = p.A744T on NM_022118.5) | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as COSV57395223; called by muse, mutect2, varscan2
- RBM46 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV55979402; called by muse, mutect2, varscan2
- RC3H1 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51202181; called by muse, mutect2, varscan2
- RECQL | c.643C>G p.R215G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs376839517, CM155199, COSV59085001; called by muse, mutect2, varscan2
- RELCH | c.3011T>C p.V1004A | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV56886442; called by muse, mutect2, varscan2
- RGS6 | c.537G>A p.K179= | Splice Region (SNP) | VAF 24/122 reads (20%) | catalogued as COSV59579345; called by muse, mutect2, varscan2
- RGS7 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746273282, COSV100464246, COSV58537660; called by muse, mutect2, varscan2
- RHOF | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932277, COSV99932308; called by muse, mutect2, varscan2
- RHOF | c.227-1G>A p.X76_splice | Splice Site (SNP) | VAF 16/24 reads (67%) | catalogued as COSV99932309; called by muse, mutect2, varscan2
- RIOK2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs112201709, COSV51613073, COSV51614681; called by muse, mutect2, varscan2
- RIOK3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.421); catalogued as COSV59773279; called by mutect2, varscan2
- RIPK4 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60187772; called by muse, mutect2, varscan2
- RIPOR1 | c.1549G>A p.G517S (on ENST00000379312 / NM_001193522.2; = p.G513S on NM_024519.4) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV50227012; called by muse, mutect2, varscan2
- RNF152 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV57184710; called by muse, mutect2, varscan2
- RNF152 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57184134; called by muse, mutect2, varscan2
- RNF213 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60624845; called by muse, mutect2
- RNF213 | c.13345C>T p.H4449Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60399321; called by muse, mutect2, varscan2
- ROBO4 | c.2051G>A p.S684N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60624679; called by muse, mutect2, varscan2
- ROS1 | c.2566C>T p.H856Y | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV63856193; called by muse, mutect2, varscan2
- RP1 | c.4963C>T p.Q1655* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV55118307; called by muse, mutect2, varscan2
- RP1 | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55114090; called by muse, mutect2, varscan2
- RPS6KB1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56677967; called by muse, mutect2, varscan2
- RPTOR | c.3490G>A p.G1164S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100156681; called by muse, mutect2, varscan2
- RTF1 | c.1339T>A p.F447I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV67478208; called by muse, mutect2, varscan2
- RUNX1T1 | c.446G>A p.R149H (on ENST00000265814 / NM_001198628.1; = p.R122H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as rs757828605, COSV56149246; called by muse, varscan2
- RUNX1T1 | c.422C>T p.S141L (on ENST00000265814 / NM_001198628.1; = p.S114L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56149264; called by muse, varscan2
- RYR2 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs267598436, COSV63689111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR4 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV55740454; called by muse, mutect2, varscan2
- SALL1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV51755559; called by muse, mutect2, varscan2
- SAMD9L | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59082146; called by muse, mutect2, varscan2
- SCIMP | c.377A>C p.E126A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV68311010; called by muse, mutect2, varscan2
- SCLT1 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs758308700, COSV55406180; called by muse, mutect2, varscan2
- SCN1A | c.3995G>A p.G1332E (on ENST00000303395 / NM_001202435.3; = p.G1321E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57672411; called by muse, mutect2, varscan2
- SCN2A | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV51843728; called by muse, mutect2, varscan2
- SCN5A | c.1508C>G p.P503R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.166); catalogued as COSV100349329; called by muse, mutect2, varscan2
- SCN7A | c.4307G>A p.W1436* | Nonsense Mutation (SNP) | VAF 44/142 reads (31%) | catalogued as COSV69272165; called by muse, mutect2, varscan2
- SCNN1G | c.810G>A p.R270= | Splice Region (SNP) | VAF 24/75 reads (32%) | catalogued as COSV55599318; called by muse, mutect2, varscan2
- SDK1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV67371895; called by muse, mutect2, varscan2
- SDK2 | c.3268C>T p.Q1090* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV66187334; called by muse, mutect2, varscan2
- SEC24A | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); catalogued as COSV59747622; called by muse, mutect2, varscan2
- SELENBP1 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64373594; called by muse, mutect2, varscan2
- SELP | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55248900; called by muse, mutect2, varscan2
- SENP1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV50290777; called by muse, mutect2, varscan2
- SERPINA6 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs775123612, COSV58585278; called by muse, mutect2, varscan2
- SETDB1 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199613890, COSV54984269; called by muse, mutect2, varscan2
- SETDB1 | c.2674A>G p.N892D | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV54984294; called by muse, mutect2, varscan2
- SETDB2 | c.2052A>T p.K684N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57903171; called by muse, mutect2, varscan2
- SFI1 | c.1300G>A p.E434K (on ENST00000400288 / NM_001007467.3; = p.E403K on NM_014775.4) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66291073; called by muse, mutect2, varscan2
- SFSWAP | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754014252, COSV55521144, COSV55525587; called by muse, mutect2, varscan2
- SHB | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1313047032, COSV66629256; called by muse, mutect2, varscan2
- SHC2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs956619823, COSV52746572; called by muse, mutect2, varscan2
- SHH | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV51919013; called by muse, mutect2
- SHISA2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs775528667, COSV60110148; called by muse, mutect2, varscan2
- SHOX | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); catalogued as COSV61861084; called by muse, mutect2, varscan2
- SHQ1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57765979; called by muse, mutect2
- SI | c.3718C>T p.R1240W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.773); catalogued as rs754850052, COSV52273747, COSV52281882; called by mutect2, varscan2
- SI | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.08); catalogued as rs755002054, COSV52281894, COSV52306245; called by muse, mutect2, varscan2
- SIAH3 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV68552081; called by muse, mutect2, varscan2
- SIGLEC12 | c.842G>A p.G281E (on ENST00000291707 / NM_053003.4; = p.G163E on NM_033329.2) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.401); catalogued as rs1288699767, COSV52462038; called by muse, mutect2, varscan2
- SIGLEC5 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.894); catalogued as rs1167282617, COSV55780296, COSV99706854; called by muse, mutect2, varscan2
- SIGLEC9 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.305); catalogued as COSV51590055; called by muse, mutect2, varscan2
- SIPA1L1 | c.4916C>A p.S1639* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV62168555, COSV62170726; called by muse, mutect2, varscan2
- SLC12A2 | c.1429T>G p.F477V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV52472052; called by muse, varscan2
- SLC12A2 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52472062; called by muse, varscan2
- SLC13A2 | c.1229G>A p.W410* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV58995437; called by muse, mutect2, varscan2
- SLC16A7 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53894014, COSV53895652; called by muse, mutect2, varscan2
- SLC16A8 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57635605; called by muse, mutect2, varscan2
- SLC17A6 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV54137115; called by muse, mutect2, varscan2
- SLC19A2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs781363092, COSV99357022; called by muse, varscan2
- SLC1A6 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55670952; called by muse, mutect2, varscan2
- SLC26A3 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60639804; called by muse, mutect2, varscan2
- SLC2A14 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as rs1157470875; called by muse, mutect2, varscan2
- SLC4A9 | c.1024C>T p.Q342* (on ENST00000507527 / NM_001258428.2; = p.Q318* on NM_031467.3) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99139331; called by muse, mutect2, varscan2
- SLC5A12 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54822049; called by muse, mutect2, varscan2
- SLC9A5 | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55362467; called by muse, mutect2, varscan2
- SLC9C1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1461907316, COSV59888892; called by muse, mutect2, varscan2
696 further variants in this file (209 protein-altering or splice-affecting, 454 silent, 33 other) are not listed here.
